TCGA case TCGA-UD-AAC7 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Western Australia. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0ac27bc8-346e-4006-a701-d9676fb91cb7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 47 years; Vital status: Dead; Days to death: 406 days (1.1 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 47.4 years (17,299 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 406 days (1.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 62 days; Days to treatment end: 92 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Days to treatment start: 62 days; Days to treatment end: 161 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 113 days; Days to treatment end: 161 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 322 days; Days to treatment end: 335 days; Treatment dose: 30 Gy; Number of fractions: 10.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Pleura, NOS. Age at diagnosis: 48.1 years (17,564 days); Days to diagnosis: 265 days; Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (2 entries)
- Day 265 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 265 days.
- Days to follow up: 406 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Mesothelin 3.12 nmol/L [Blood test normal range lower: 0.3; Blood test normal range upper: 2.5].
- Creatinine 71 mg/dL [Blood test normal range lower: 15; Blood test normal range upper: 110].

Exposures
- Exposure type: Asbestos; Exposure source: Occupational.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UD-AAC7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 570 mg.
  Slide TCGA-UD-AAC7-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UD-AAC7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UD-AAC7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Serum mesothelin prior treatment: 3.121.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 3: Pharmaceutical therapy drug name: Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 406 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 406 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 265 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UD-AAC7-01A-11D-A39Q-01): tumor purity 0.72, ploidy 1.76, whole-genome doublings 0.
